Somatic mutation profile of tumor specimen 0DIPLF from CCDI case PBBWDY, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Dead; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 2.4 years (878 days).
Specimen 0DIPLF: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c2b40daf-a713-43eb-8317-3ff94fbc7149.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DIPKV (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/66b4ef29-f318-4507-97e0-f105513ba745

The open-access MAF lists 5 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 3, Nonsense Mutation 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SCN4A | c.3394C>T p.R1132W | Missense Mutation (SNP) | VAF 113/501 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs778176181, COSV101438280; called by muse, varscan2
- CPOX | c.853C>T p.P285S | Missense Mutation (SNP) | VAF 145/410 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- POLD3 | c.1216G>T p.E406* | Nonsense Mutation (SNP) | VAF 46/292 reads (16%) | called by muse, varscan2
- WDFY4 | c.1740C>A p.D580E | Missense Mutation (SNP) | VAF 128/344 reads (37%) | SIFT tolerated (0.46); PolyPhen benign (0.015); called by muse, varscan2
- NOL4L | c.1122C>T p.A374= | Silent (SNP) | VAF 212/490 reads (43%) | called by muse, varscan2
